Somatic mutation profile of tumor specimen ALCH-B1LG-TTP1-A (aliquot ALCH-B1LG-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1LG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.4 years (27,177 days).
Specimen ALCH-B1LG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a35904-ede1-4a6a-98de-ad6ed6028521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LG-NB1-A (Blood Derived Normal), aliquot ALCH-B1LG-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4c26239-b634-469f-bf11-f9513063c920

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MARCO | c.427A>T p.M143L | Missense Mutation (SNP) | VAF 25/591 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59053453; called by muse, mutect2
- PPP1R3E | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.646); catalogued as rs983572006; called by muse, mutect2
- SLC35E1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1315871221; called by muse, mutect2
- TP53 | c.833del p.P278Lfs*67 | Frame Shift Del (DEL) | VAF 86/838 reads (10%) | catalogued as CM961376, COSV52661225, COSV52665769, COSV52678063; called by mutect2, varscan2
- ABL2 | c.580A>G p.S194G (on ENST00000502732 / NM_007314.4; = p.S179G on NM_005158.5) | Missense Mutation (SNP) | VAF 78/941 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHM | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- PCDHGA4 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.44); called by muse, mutect2
- SDK1 | c.6384C>T p.A2128= | Splice Region (SNP) | VAF 20/413 reads (5%) | called by muse, mutect2
- SKIDA1 | c.2504A>T p.N835I | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- TARBP1 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- TDRD6 | c.2854G>T p.V952L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2
- UMODL1 | c.2297T>A p.L766Q (on ENST00000408910 / NM_001004416.2; = p.L894Q on NM_173568.3) | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.866); called by muse, mutect2
- CDH10 | c.780A>T p.T260= | Silent (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- GCLC | c.1542A>G p.A514= (on ENST00000643939; = p.A512= on NM_001498.4) | Silent (SNP) | VAF 100/1344 reads (7%) | called by muse, mutect2
- PCDHB12 | c.363C>T p.L121= | Silent (SNP) | VAF 55/447 reads (12%) | catalogued as rs782089212; called by muse, mutect2, varscan2
- VAPB | c.*268C>T | 3'UTR (SNP) | VAF 58/508 reads (11%) | called by muse, mutect2, varscan2
